Somatic mutation profile of tumor specimen TCGA-06-0747-01A (aliquot TCGA-06-0747-01A-01D-1492-08) from TCGA case TCGA-06-0747, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.8 years (19,657 days).
Specimen TCGA-06-0747-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39394d69-f54d-4f55-8a39-241186d17ff8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0747-10A (Blood Derived Normal), aliquot TCGA-06-0747-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3dfcf466-38aa-4c8f-beae-e4eba6cfa4ca

The open-access MAF lists 76 somatic variants for this specimen: 58 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 50, Silent 18, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 3132/3260 reads (96%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, varscan2
- ABCA4 | c.1433T>A p.I478N | Missense Mutation (SNP) | VAF 143/295 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV64677153; called by muse, mutect2, varscan2
- ABCD2 | c.1169C>T p.T390I | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.275); catalogued as COSV58054568; called by muse, mutect2, varscan2
- ADGRL4 | c.251G>C p.C84S | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66058631, COSV66065099; called by muse, mutect2, varscan2
- AHNAK2 | c.16944G>A p.W5648* | Nonsense Mutation (SNP) | VAF 32/55 reads (58%) | catalogued as rs1354318101, COSV60928182; called by muse, mutect2, varscan2
- AP002512.3 | c.1220C>G p.A407G | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.808); catalogued as COSV54408554; called by muse, mutect2, varscan2
- ATP1A2 | c.2559G>C p.Q853H | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as COSV63405644; called by muse, mutect2, varscan2
- BEST2 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 58/212 reads (27%) | catalogued as COSV50376325; called by muse, mutect2, varscan2
- BPIFC | c.704G>A p.S235N | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55915413; called by muse, mutect2, varscan2
- CACNA1C | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100216972, COSV59762894; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5528T>G p.M1843R | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV62577476; called by muse, mutect2, varscan2
- COL20A1 | c.1745G>A p.R582K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.747); catalogued as COSV58926077; called by muse, mutect2, varscan2
- DENND2A | c.1613A>G p.N538S | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV52057743; called by muse, mutect2, varscan2
- DLGAP4 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1352274107, COSV59422049, COSV59424745; called by muse, mutect2, varscan2
- DTX4 | c.878A>G p.N293S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV57094452; called by muse, mutect2, varscan2
- ECPAS | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52206008; called by muse, mutect2, varscan2
- EEF1A1 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV58549515; called by muse, mutect2, varscan2
- EPB41L3 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as rs780498839, COSV59446714; called by muse, mutect2, varscan2
- GBX1 | c.844T>A p.C282S | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV52548918; called by muse, mutect2, varscan2
- GNB1L | c.353G>A p.S118N | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV61549649; called by muse, mutect2, varscan2
- HCN1 | c.2387A>T p.E796V | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV57533783; called by muse, mutect2, varscan2
- HYDIN | c.10393G>A p.V3465M | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs373714588; called by muse, mutect2, varscan2
- KIF17 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139912475; called by muse, mutect2, varscan2
- LAMA3 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.284); catalogued as rs1344062987, COSV58078239; called by muse, mutect2, varscan2
- LRRC3B | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs752250087, COSV67522467; called by muse, mutect2, varscan2
- MAP1S | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as rs540976741, COSV60724357; called by muse, mutect2, varscan2
- MBL2 | c.5C>A p.S2Y | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.41); PolyPhen benign (0.125); catalogued as COSV64758084, COSV64759290; called by muse, mutect2, varscan2
- MGMT | c.245C>T p.A82V (on ENST00000306010; = p.A51V on NM_002412.5) | Missense Mutation (SNP) | VAF 85/99 reads (86%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs749868332, COSV60033630; called by muse, mutect2, varscan2
- MYLK | c.1928C>G p.T643S | Missense Mutation (SNP) | VAF 271/624 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV60620445; called by muse, mutect2, varscan2
- NFATC2 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 45/194 reads (23%) | catalogued as rs1305798984, COSV65360308; called by muse, mutect2, varscan2
- NLRP12 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 93/210 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs781341758, COSV60743424, COSV60751214; called by muse, mutect2, varscan2
- NLRP3 | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 79/168 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV60230195; called by muse, varscan2
- OR1J1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.125); catalogued as rs762965619, COSV52237360, COSV52239396; called by muse, mutect2, varscan2
- OR5AS1 | c.196T>G p.L66V | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57983043; called by muse, mutect2, varscan2
- OR7A10 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.309); catalogued as COSV50166736; called by muse, mutect2, varscan2
- PCDH15 | c.2068G>C p.A690P | Missense Mutation (SNP) | VAF 108/132 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57380772; called by muse, mutect2, varscan2
- PDCD1 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs866653159, COSV57692062; called by muse, mutect2, varscan2
- PDE3B | c.2066G>A p.G689E | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56389738, COSV99962621; called by muse, mutect2, varscan2
- PJA2 | c.1792G>T p.A598S | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV63274319; called by muse, mutect2, varscan2
- PPP6R1 | c.2614C>A p.P872T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV58985153; called by muse, mutect2, varscan2
- SHLD1 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57439117; called by muse, mutect2, varscan2
- SLC4A1 | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as rs767620009, COSV52262690, COSV99293066; called by muse, mutect2, varscan2
- SLC9A4 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as rs764521439, COSV54838348; called by muse, mutect2, varscan2
- ST3GAL6 | c.639G>C p.K213N | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV54584370; called by muse, mutect2, varscan2
- SYN3 | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 80/100 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60515115; called by muse, mutect2, varscan2
- TLR6 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV67935726; called by muse, mutect2, varscan2
- TMEM30A | c.850C>G p.P284A | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV57876802; called by muse, mutect2, varscan2
- TMTC1 | c.2170-1G>T p.X724_splice (on ENST00000539277 / NM_001193451.2; = p.X616_splice on NM_175861.3) | Splice Site (SNP) | VAF 5/98 reads (5%) | catalogued as COSV55492032; called by muse, mutect2
- TTK | c.1996G>C p.G666R | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100036017, COSV57886460; called by muse, mutect2
- TTN | c.33158T>C p.V11053A (on ENST00000591111; = p.V10126A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/245 reads (40%) | PolyPhen benign (0.003); catalogued as COSV60297288; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3757C>T p.H1253Y | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV51959699; called by muse, mutect2, varscan2
- VPS8 | c.1034G>A p.R345Q (on ENST00000625842 / NM_001349294.1; = p.R343Q on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs201816956; called by muse, mutect2, varscan2
- ZIC4 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV67173829, COSV67174472; called by muse, mutect2, varscan2
- ZNF479 | c.1225T>C p.Y409H | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV58644381; called by muse, mutect2, varscan2
- ARFGEF1 | c.3462_3465del p.E1154Dfs*15 | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | called by mutect2, pindel, varscan2
- CPEB4 | c.818del p.H273Lfs*49 | Frame Shift Del (DEL) | VAF 56/410 reads (14%) | called by mutect2, pindel, varscan2
- GNPDA1 | c.280_282del p.F94del | In Frame Del (DEL) | VAF 45/150 reads (30%) | called by pindel, varscan2
- RANBP2 | c.5892dup p.D1965Rfs*21 | Frame Shift Ins (INS) | VAF 49/436 reads (11%) | called by mutect2, pindel, varscan2
- AGO2 | c.621G>A p.R207= | Silent (SNP) | VAF 55/152 reads (36%) | catalogued as rs1324487764, COSV55046423; called by muse, mutect2, varscan2
- AL592490.1 | c.2406C>T p.G802= | Silent (SNP) | VAF 55/129 reads (43%) | catalogued as COSV69427601; called by muse, mutect2, varscan2
- CEP152 | c.2490A>C p.I830= | Silent (SNP) | VAF 83/178 reads (47%) | catalogued as COSV57863793; called by muse, mutect2, varscan2
- EGFR | c.867C>T p.A289= | Silent (SNP) | VAF 3139/3264 reads (96%) | catalogued as COSV51854604; called by muse, varscan2
- FBF1 | c.2190C>T p.A730= (on ENST00000586717; = p.A744= on NM_001319193.1) | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs375382563; called by muse, mutect2, varscan2
- FUT1 | c.711C>T p.G237= | Silent (SNP) | VAF 100/236 reads (42%) | catalogued as COSV59567506; called by muse, mutect2, varscan2
- GPR85 | c.6G>A p.A2= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs767852001, COSV51784596, COSV99775106; called by muse, mutect2, varscan2
- IFNA10 | c.102T>C p.N34= | Silent (SNP) | VAF 73/99 reads (74%) | catalogued as COSV53332201; called by muse, mutect2, varscan2
- ITIH4 | c.2328G>A p.E776= | Silent (SNP) | VAF 83/193 reads (43%) | catalogued as COSV56578051; called by muse, mutect2, varscan2
- MST1R | c.849T>C p.L283= | Silent (SNP) | VAF 110/221 reads (50%) | catalogued as COSV56573103; called by muse, mutect2, varscan2
- OR5K1 | c.747A>G p.S249= | Silent (SNP) | VAF 71/141 reads (50%) | catalogued as rs771218467, COSV60305194; called by muse, mutect2, varscan2
- PCDH11Y | c.3564C>A p.L1188= | Silent (SNP) | VAF 132/144 reads (92%) | catalogued as COSV53089858; called by muse, mutect2, varscan2
- PCID2 | c.54C>T p.D18= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV55814973; called by muse, mutect2, varscan2
- PRDM8 | c.585C>T p.G195= | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as rs1457977666, COSV60204837; called by muse, mutect2
- PRSS16 | c.1143C>T p.F381= | Silent (SNP) | VAF 109/258 reads (42%) | catalogued as rs191407230; called by muse, varscan2
- RPS20 | c.222T>A p.S74= | Silent (SNP) | VAF 92/183 reads (50%) | catalogued as COSV50536938; called by muse, mutect2, varscan2
- STYXL2 | c.30G>A p.E10= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV54809374; called by muse, mutect2, varscan2
- TAF4B | c.1782A>G p.A594= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs201212556, COSV52309460; called by muse, mutect2
